Somatic mutation profile of tumor specimen MMRF_2017_1_BM_CD138pos (aliquot MMRF_2017_1_BM_CD138pos_T1_KHS5U_L08809) from MMRF case MMRF_2017, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.7 years (30,211 days).
Specimen MMRF_2017_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3fae7d8-3091-44c1-8e82-be34bda27cb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2017_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2017_1_PB_WBC_C3_KHS5U_L08821; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76901e0d-2192-4a5c-b447-53b96a2de969

The open-access MAF lists 77 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 19, Silent 9, Intron 6, Nonsense Mutation 2, 5'UTR 2, RNA 2, Splice Site 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 46/100 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 95/195 reads (49%) | catalogued as COSV100718982, COSV61363169; called by muse, mutect2, varscan2
- BSN | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | catalogued as COSV99609946; called by muse, mutect2, varscan2
- CDH18 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV99937554; called by muse, mutect2, varscan2
- E2F3 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV60899670; called by muse, mutect2, varscan2
- IGHV2-70D | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, varscan2
- INSYN2A | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs144141274, COSV99732163; called by muse, mutect2, varscan2
- KCNH2 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1402460942; called by muse, mutect2, varscan2
- NSUN2 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99243080; called by muse, mutect2, varscan2
- SLC19A1 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as rs746905281; called by muse, mutect2, varscan2
- SPATA31D1 | c.4686G>T p.M1562I | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs1402986205; called by muse, mutect2
- STAC | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs145771131; called by muse, mutect2, varscan2
- TTN | c.102088G>A p.D34030N (on ENST00000591111; = p.D26606N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/149 reads (9%) | PolyPhen benign (0.098); catalogued as rs1397922467, COSV60316325; called by muse, mutect2
- ULK1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1372824316, COSV58856766; called by muse, mutect2, varscan2
- ADAMTS20 | c.3882T>A p.N1294K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BAG4 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- BNC1 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1E | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALU | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEBPG | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CFAP20DC | c.1184T>G p.L395R (on ENST00000482387 / NM_001351530.2; = p.L270R on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CLIC6 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FILIP1L | c.3019G>A p.V1007M (on ENST00000354552 / NM_182909.3; = p.V767M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLRT3 | c.371T>A p.L124H | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD3 | c.92+2T>G p.X31_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- IGHV1-69D | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV1-5 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, varscan2
- KMT2B | c.7540G>A p.V2514I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MIS18A | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OTUD4 | c.497-2A>G p.X166_splice (on ENST00000447906 / NM_001366057.1; = p.X101_splice on NM_017493.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- SGCZ | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEK | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TJP1 | c.3488C>G p.P1163R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TULP2 | c.1455T>A p.H485Q | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- WNK2 | c.2986C>G p.P996A | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF641 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- AMOTL2 | c.681T>G p.T227= | Silent (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- CDK13 | c.4005C>T p.Y1335= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as rs117406419; called by muse, mutect2, varscan2
- CHD5 | c.3345C>G p.V1115= | Silent (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- FAT4 | c.6858T>C p.D2286= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as COSV58699280; called by muse, mutect2, varscan2
- OR1S2 | c.580T>C p.L194= | Silent (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- OTOF | c.4722G>C p.G1574= (on ENST00000272371 / NM_194248.3; = p.G807= on NM_004802.4) | Silent (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- PKHD1 | c.8316T>G p.L2772= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- REXO1 | c.2139C>G p.A713= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- WDR11 | c.717T>C p.A239= | Silent (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- AC093791.1 | n.490G>A | RNA (SNP) | VAF 89/164 reads (54%) | called by muse, mutect2, varscan2
- ACSL6 | c.915+104dup | Intron (INS) | VAF 4/34 reads (12%) | catalogued as rs1181256828; called by pindel, varscan2
- ALKBH4 | c.*85C>T | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- ARL5B | c.*8G>T | 3'UTR (SNP) | VAF 16/326 reads (5%) | catalogued as rs370695851; called by muse, mutect2
- BCL11B | c.*4408A>C | 3'UTR (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- C1orf74 | c.*59T>C | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CASP10 | c.1415+8117C>T | Intron (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- CPEB4 | c.*768del | 3'UTR (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- DUSP22 | c.509-113G>A | Intron (SNP) | VAF 126/424 reads (30%) | catalogued as rs1322377107; called by muse, mutect2, varscan2
- EHMT1 | c.*34G>C | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- ENDOV | chr17:80415000 C>T | 5'Flank (SNP) | VAF 97/203 reads (48%) | called by muse, mutect2, varscan2
- FAM20C | c.864-17411C>A | Intron (SNP) | VAF 32/57 reads (56%) | called by muse, varscan2
- FICD | c.*662del | 3'UTR (DEL) | VAF 16/47 reads (34%) | catalogued as rs889606437; called by mutect2, varscan2
- FKBP1C | c.*421del | 3'UTR (DEL) | VAF 67/200 reads (34%) | called by mutect2, pindel, varscan2
- FRG2C | c.*406T>C | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- FRMD4A | c.46-149538C>G | Intron (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- LINC02693 | n.872T>G | RNA (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- MTDH | c.*849T>C | 3'UTR (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- NUBPL | c.*106T>A | 3'UTR (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2
- NUBPL | c.*448T>C | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- PCK2 | chr14:24094092 G>A | 5'Flank (SNP) | VAF 11/30 reads (37%) | catalogued as rs1264436010; called by muse, mutect2, varscan2
- PTGR2 | c.*1121_*1122insT | 3'UTR (INS) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- RGSL1 | c.*66T>A | 3'UTR (SNP) | VAF 69/157 reads (44%) | called by muse, mutect2, varscan2
- SLC26A9 | c.553-59G>A | Intron (SNP) | VAF 34/71 reads (48%) | catalogued as rs542014603, COSV61603608; called by muse, mutect2, varscan2
- SLC2A9 | c.-12T>C | 5'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- SLC40A1 | c.*1008C>T | 3'UTR (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- SYNRG | c.*1100G>A | 3'UTR (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- TMEM175 | c.-64C>T | 5'UTR (SNP) | VAF 13/36 reads (36%) | catalogued as rs758487337; called by muse, mutect2, varscan2
- TNC | c.*614G>A | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- TNS1 | c.*2090C>G | 3'UTR (SNP) | VAF 76/163 reads (47%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*4955T>C | 3'UTR (SNP) | VAF 5/21 reads (24%) | catalogued as rs1286293245; called by muse, mutect2
